Surgical pathology report (de-identified scan), TCGA case TCGA-14-1451, project TCGA-GBM (Glioblastoma Multiforme), tissue source site Emory University, specimen TCGA-14-1451-01A (Primary Tumor).

==Section 1 of 1: Anatomic Pathology Ref
==Cum Auth [REDACTED] EMR EVENT Id. [REDACTED]

Front: [REDACTED]

Accession Number: [REDACTED]

Patient Number: [REDACTED]

Date Collected: [REDACTED]

Financial Number: [REDACTED]

Date Received: [REDACTED]

Room/Bed: [REDACTED]

PT: [REDACTED]

Admitting Physician: [REDACTED]

Ordering Physician: [REDACTED]

SURGICAL PATHOLOGY REPORT

DIAGNOSIS:

1. BRAIN, LEFT OCCIPITAL, BIOPSY:
- GLIOBLASTOMA MULTIFORME.
2. BRAIN, LEFT OCCIPITAL, EXCISION:
- GLIOBLASTOMA MULTIFORME.

TCGA-14-1451

SPECIMEN:

1. Left occipital brain lesion.
2. Left occipital brain lesion.

CLINICAL HISTORY/OPERATIVE FINDINGS:

Brain tumor.

6. DESCRIPTION:

This case consists of two parts. Part #1 is received fresh for intraoperative consultation and part #2 is received in formalin, each part labeled with the patient's name and hospital number.

Part #1 is received as "left occipital brain lesion" and consists of multiple fragments of tan-pink tissue, measuring 1.5 x 1.5 x 0.8 cm in aggregate. A portion of the specimen is submitted for frozen section diagnosis and the remainder of the cryoblock is resubmitted in cassette "FS1A." The remainder of the specimen is submitted in cassette "1B."

Part #2 is received as "left occipital brain lesion" and consists of multiple fragments of tan-brown tissue measuring 5.3 x 3.5 x 1.5 cm in aggregate. The specimen is serially sectioned and representative sections are submitted in cassettes "2A" through "2F."

INTRAOPERATIVE CONSULTATION:

FS1A: LEFT OCCIPITAL BRAIN, BIOPSY (FROZEN SECTION): GLIOBLASTOMA MULTIFORME.

MICROSCOPIC DESCRIPTION:

Microscopic examination performed.

Source: NCI Genomic Data Commons file 0cd11c20-83c8-4d36-9ae8-034821441e35 (TCGA-14-1451.0B182102-28A4-43D7-89E7-1CFCA42745EA.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).